Somatic mutation profile of tumor specimen 0DIPLC from CCDI case PBBVPK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dermatofibrosarcoma protuberans, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 15.5 years (5,644 days).
Specimen 0DIPLC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb49a995-100a-4332-bbbf-465400722f36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06a01ec9-c768-4938-a6a3-b4e37f43ac90

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETBP1 | c.3880G>C p.D1294H | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV56328491; called by muse, mutect2
- AFF4 | c.528dup p.R177Tfs*17 | Frame Shift Ins (INS) | VAF 68/302 reads (23%) | called by mutect2, varscan2
- COL1A1 | c.3402_3413dup p.S1135_A1138dup | In Frame Ins (INS) | VAF 248/730 reads (34%) | called by mutect2, varscan2
- ZBTB3 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEC | c.11832C>A p.G3944= (on ENST00000322810 / NM_201380.4; = p.G3834= on NM_000445.5) | Silent (SNP) | VAF 69/267 reads (26%) | catalogued as rs782144786; called by muse, mutect2, varscan2
- SERPINE2 | c.135G>A p.S45= | Silent (SNP) | VAF 79/318 reads (25%) | catalogued as rs771123562, COSV51456892; called by muse, mutect2, varscan2
